Gene-level copy-number profile of tumor specimen C3L-09554-05 from CPTAC case C3L-09554, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 79.9 years (29,181 days).
Specimen C3L-09554-05: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 42eba3cf-1174-4129-ac3a-af8bc7fa89f8.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-09554-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,232 have no estimate.
https://portal.gdc.cancer.gov/files/c4fe3ddc-628b-4845-8521-7cb15373b4e2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,282; copy number 2: 51,818; copy number 3: 4,291.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 2,266. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
